Somatic mutation profile of tumor specimen TCGA-CV-A461-01A (aliquot TCGA-CV-A461-01A-41D-A25Y-08) from TCGA case TCGA-CV-A461, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 65.6 years (23,955 days).
Specimen TCGA-CV-A461-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8aee21a6-8583-4b3a-bb82-711030b366fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A461-10A (Blood Derived Normal), aliquot TCGA-CV-A461-10A-01D-A25Y-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c1eccad-be79-4625-b9dc-c3a8e183bc01

The open-access MAF lists 659 somatic variants for this specimen: 494 protein-altering or splice-affecting, 153 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 409, Silent 153, Nonsense Mutation 29, Frame Shift Del 20, Splice Site 18, Splice Region 8, Frame Shift Ins 8, Intron 5, RNA 4, 3'Flank 2, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A1 | c.1575+1G>A p.X525_splice | Splice Site (SNP) | VAF 4/20 reads (20%) | catalogued as rs1002726737, COSV62611192; ClinVar: likely pathogenic; called by muse, mutect2
- KMT2D | c.8214del p.F2739Lfs*18 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | catalogued as rs1565790685; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3141T>A p.H1047Q | Missense Mutation (SNP) | VAF 63/145 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV55875891, COSV55920782; called by muse, mutect2, varscan2
- TP53 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 17/60 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.1619C>T p.S540L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as COSV100382675; called by muse, mutect2, varscan2
- ACADL | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.048); catalogued as COSV99284551; called by muse, mutect2, varscan2
- ACSBG2 | c.738C>T p.N246= | Splice Region (SNP) | VAF 24/93 reads (26%) | catalogued as rs560299046, COSV53123538; called by muse, mutect2, varscan2
- ACSM2B | c.98T>A p.L33Q | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100312361; called by muse, mutect2, varscan2
- ACTL7B | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.295); catalogued as COSV65927988; called by muse, mutect2
- ADAM19 | c.2070C>G p.I690M | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.269); catalogued as COSV57436143, COSV99976272; called by muse, mutect2
- ADAM21 | c.911T>C p.I304T | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.281); catalogued as COSV99960575; called by muse, mutect2, varscan2
- ADAMTS7 | c.735G>T p.E245D | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101182991, COSV101183019; called by muse, mutect2, varscan2
- ADCY2 | c.634A>T p.M212L | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as COSV100601913; called by muse, mutect2, varscan2
- ADGRA1 | c.540C>G p.Y180* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV101192645, COSV66927407; called by muse, varscan2
- ADGRB1 | c.3053T>C p.L1018P | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV100029295; called by muse, mutect2, varscan2
- ADGRG4 | c.5968T>A p.S1990T | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.033); catalogued as COSV99794501; called by muse, mutect2, varscan2
- ADGRG6 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs756919427, COSV99745970, COSV99748607; called by muse, mutect2, varscan2
- ADGRV1 | c.7750A>G p.N2584D | Missense Mutation (SNP) | VAF 58/320 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs971279294, COSV101315535; called by muse, mutect2, varscan2
- ADSS1 | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV58274746; called by muse, mutect2, varscan2
- AGGF1 | c.616G>C p.G206R | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV100461552, COSV57231343; called by muse, mutect2, varscan2
- ALDH1A2 | c.772A>C p.K258Q | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99990429; called by muse, mutect2, varscan2
- ALDH3B1 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs201905211; called by muse, mutect2, varscan2
- AMOT | c.2989G>C p.A997P (on ENST00000371959 / NM_001113490.1; = p.A588P on NM_133265.3) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV100494778, COSV59064912; called by muse, mutect2, varscan2
- ANK2 | c.5671T>C p.S1891P | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100000003; called by muse, mutect2, varscan2
- ANKEF1 | c.2282A>T p.K761M | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV101000991; called by muse, mutect2, varscan2
- ANKRD42 | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs1453182758, COSV99473544; called by muse, mutect2, varscan2
- ANKRD52 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99921066; called by muse, mutect2
- ANO9 | c.1447G>T p.G483C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100229825; called by muse, mutect2, varscan2
- ANP32A | c.171C>G p.I57M | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV99142977; called by muse, mutect2, varscan2
- AOPEP | c.1700G>A p.G567E (on ENST00000375315 / NM_001193329.1; = p.G468E on NM_032823.5) | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99948895; called by muse, mutect2, varscan2
- AP4E1 | c.2214G>A p.M738I | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV55916630; called by muse, mutect2, varscan2
- APLP1 | c.1626C>A p.N542K (on ENST00000221891 / NM_001024807.3; = p.N541K on NM_005166.4) | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99697524; called by muse, mutect2
- APOBEC3C | c.470G>C p.W157S | Missense Mutation (SNP) | VAF 65/353 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99328800; called by muse, mutect2, varscan2
- AQP10 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 95/288 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV61475267; called by muse, mutect2, varscan2
- ARHGAP11A | c.1562G>T p.W521L | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100853166; called by muse, mutect2, varscan2
- ARHGAP21 | c.4723G>T p.E1575* | Nonsense Mutation (SNP) | VAF 31/141 reads (22%) | catalogued as COSV100255827; called by muse, mutect2, varscan2
- ARHGAP28 | c.586A>C p.T196P (on ENST00000383472 / NM_001366230.1; = p.T37P on NM_001010000.3) | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99148694; called by muse, mutect2, varscan2
- ARHGAP5 | c.2965C>T p.P989S | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.395); catalogued as COSV100565049; called by muse, mutect2, varscan2
- ARHGEF40 | c.809C>A p.T270K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100070052, COSV53881023; called by muse, mutect2
- ARL6IP6 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs749893071, COSV100423895; called by muse, mutect2, varscan2
- ASIC5 | c.868C>G p.H290D | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV101611108; called by muse, mutect2, varscan2
- ASTL | c.365A>G p.E122G | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.237); catalogued as COSV100668256; called by muse, mutect2, varscan2
- ATIC | c.183G>T p.L61F | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52694437; called by muse, mutect2, varscan2
- ATRNL1 | c.3904G>T p.G1302W | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100369488; called by muse, mutect2
- AUTS2 | c.3686dup p.R1230Pfs*52 | Frame Shift Ins (INS) | VAF 7/54 reads (13%) | catalogued as rs1287439714; called by mutect2, pindel, varscan2
- AVEN | c.268-2A>T p.X90_splice | Splice Site (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100145304; called by muse, mutect2, varscan2
- BCAT1 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99678189; called by muse, mutect2, varscan2
- BFSP1 | c.1550C>G p.P517R | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100925307, COSV100925311; called by muse, mutect2, varscan2
- BIRC6 | c.2344G>T p.G782C | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV101427918; called by muse, mutect2, varscan2
- BPIFA2 | c.453C>G p.D151E | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.73); catalogued as COSV99487775; called by muse, mutect2, varscan2
- BRAF | c.2023T>A p.F675I (on ENST00000288602 / NM_001374244.1; = p.F635I on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV99952510; called by muse, mutect2, varscan2
- BRD9 | c.1213G>C p.E405Q | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV100056900; called by muse, mutect2, varscan2
- BRINP1 | c.1362C>A p.Y454* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV99774590; called by muse, mutect2, varscan2
- BRINP1 | c.335C>G p.P112R | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99774591; called by muse, mutect2, varscan2
- BRINP3 | c.569G>C p.S190T | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.973); catalogued as COSV100818415; called by muse, mutect2, varscan2
- BROX | c.796A>T p.K266* | Nonsense Mutation (SNP) | VAF 24/79 reads (30%) | catalogued as COSV100572075; called by muse, mutect2, varscan2
- BTNL9 | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100576099; called by muse, mutect2, varscan2
- C10orf90 | c.1925G>T p.C642F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV52953251, COSV99503210; called by muse, mutect2, varscan2
- C12orf40 | c.1517T>A p.I506K | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100209681; called by muse, mutect2, varscan2
- C2CD3 | c.3649G>T p.A1217S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV100486278; called by muse, mutect2, varscan2
- C7 | c.2296C>A p.P766T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV100495463; called by muse, mutect2, varscan2
- C8B | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64778124; called by muse, mutect2, varscan2
- CACNA1E | c.6592C>T p.Q2198* (on ENST00000367573 / NM_001205293.3; = p.Q2155* on NM_000721.4) | Nonsense Mutation (SNP) | VAF 32/122 reads (26%) | catalogued as COSV100701348, COSV62433984; called by muse, mutect2, varscan2
- CACNA1E | c.6861G>T p.R2287S (on ENST00000367573 / NM_001205293.3; = p.R2244S on NM_000721.4) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.275); catalogued as COSV100701350; called by muse, mutect2, varscan2
- CACNG2 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV100268562; called by muse, mutect2, varscan2
- CAMTA1 | c.2425G>A p.G809R | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.674); catalogued as rs748817784, COSV57895427; called by muse, mutect2, varscan2
- CASP7 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.953); catalogued as COSV100614795, COSV61882461; called by muse, mutect2, varscan2
- CBLB | c.2794G>C p.V932L | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT tolerated, low confidence (0.56); PolyPhen probably damaging (0.992); catalogued as COSV99912777, COSV99914437; called by muse, mutect2, varscan2
- CCDC170 | c.2135A>G p.Q712R | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV99498166; called by muse, mutect2
- CCDC38 | c.135A>T p.E45D | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV100717398; called by muse, mutect2, varscan2
- CCDC54 | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99660141; called by muse, mutect2, varscan2
- CCDC85A | c.772C>A p.H258N | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.535); catalogued as COSV68150819; called by muse, mutect2, varscan2
- CD36 | c.1364T>A p.M455K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as rs779394558, COSV99987219; called by muse, mutect2, varscan2
- CDC14B | c.964G>T p.G322C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99685297; called by muse, mutect2, varscan2
- CDH23 | c.372T>A p.D124E | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99819147; called by muse, mutect2
- CEP57 | c.608A>C p.Q203P | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100334592; called by muse, mutect2, varscan2
- CHD5 | c.2716G>T p.E906* | Nonsense Mutation (SNP) | VAF 16/91 reads (18%) | catalogued as COSV52413742, COSV99312627; called by muse, mutect2, varscan2
- CHD6 | c.3733G>T p.G1245* | Nonsense Mutation (SNP) | VAF 27/166 reads (16%) | catalogued as COSV100497817; called by muse, mutect2, varscan2
- CHD7 | c.4867G>C p.D1623H | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101418022; called by muse, mutect2, varscan2
- CHL1 | c.2097G>C p.Q699H (on ENST00000397491 / NM_001253387.1; = p.Q715H on NM_006614.4) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV99850257; called by muse, mutect2, varscan2
- CHP2 | c.215C>A p.P72H | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV100270048; called by muse, mutect2, varscan2
- CKAP5 | c.2488A>G p.S830G | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761653051, COSV100370464, COSV100371374; called by muse, mutect2, varscan2
- CLASP1 | c.3760C>T p.R1254C | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV55330094; called by muse, mutect2, varscan2
- CMA1 | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.401); catalogued as COSV99157134; called by muse, mutect2, varscan2
- CNDP1 | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 66/249 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as COSV100722198, COSV62594811; called by muse, mutect2, varscan2
- CNGA3 | c.1091C>A p.T364N | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99736150; called by muse, mutect2, varscan2
- CNGA4 | c.597C>A p.D199E | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV101171747; called by muse, mutect2, varscan2
- COBL | c.1536C>A p.S512R | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.302); catalogued as COSV99471454; called by muse, mutect2, varscan2
- COL11A1 | c.1822C>A p.L608M | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100615349; called by muse, mutect2, varscan2
- COL19A1 | c.1383+1G>A p.X461_splice | Splice Site (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100505337; called by muse, mutect2, varscan2
- COL22A1 | c.3793C>A p.L1265I | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.87); catalogued as COSV57343304; called by muse, mutect2, varscan2
- COL22A1 | c.2833C>A p.P945T | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100276580; called by muse, mutect2, varscan2
- COL22A1 | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.656); catalogued as COSV100276583; called by muse, mutect2, varscan2
- COL22A1 | c.1705-1G>T p.X569_splice | Splice Site (SNP) | VAF 11/65 reads (17%) | catalogued as COSV57363005; called by muse, mutect2, varscan2
- COL27A1 | c.1908G>T p.P636= | Splice Region (SNP) | VAF 22/122 reads (18%) | catalogued as COSV100620750; called by muse, mutect2, varscan2
- COL4A3 | c.701T>C p.L234S | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV101169995; called by muse, mutect2, varscan2
- COL4A5 | c.3976C>T p.P1326S | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.476); catalogued as rs1421624790, COSV100089679, COSV60371938; called by muse, mutect2, varscan2
- COL5A2 | c.1484G>T p.G495V | Missense Mutation (SNP) | VAF 84/317 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100880038; called by muse, mutect2, varscan2
- CPA6 | c.953G>A p.R318K | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99912660; called by muse, mutect2, varscan2
- CPB2 | c.74+1G>A p.X25_splice | Splice Site (SNP) | VAF 14/44 reads (32%) | catalogued as rs778911564, COSV99472972; called by muse, mutect2, varscan2
- CPN1 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV100962558, COSV64942230; called by muse, mutect2, varscan2
- CREB3L2 | c.145G>T p.G49C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57800293; called by muse, mutect2, varscan2
- CROCC | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100978072; called by muse, mutect2, varscan2
- CSF3R | c.2506T>C p.F836L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs780460174, COSV100117387; called by muse, varscan2
- CSNK1G3 | c.1136A>G p.H379R | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as COSV100631343; called by muse, mutect2, varscan2
- CYP46A1 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.136); catalogued as COSV99952470; called by muse, mutect2, varscan2
- DAPK1 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100801145; called by muse, mutect2, varscan2
- DCAF12L1 | c.519C>G p.S173R | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100948114; called by muse, mutect2, varscan2
- DCAF4L2 | c.1094G>T p.S365I | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100150386, COSV60477329; called by muse, mutect2, varscan2
- DCAF8L1 | c.1169C>A p.P390Q | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV101491399; called by muse, mutect2, varscan2
- DCDC2 | c.1204G>T p.A402S | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV101015254; called by muse, mutect2, varscan2
- DDHD2 | c.1118G>T p.S373I | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV101240522; called by muse, mutect2, varscan2
- DDR2 | c.216G>C p.W72C | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100906218, COSV100906734; called by muse, mutect2, varscan2
- DECR1 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99616031; called by muse, mutect2, varscan2
- DEDD2 | c.500_502del p.G167del | In Frame Del (DEL) | VAF 41/121 reads (34%) | catalogued as rs753251460; called by pindel, varscan2
- DEFB129 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 28/134 reads (21%) | catalogued as COSV99857355; called by muse, mutect2, varscan2
- DEPDC7 | c.590A>G p.Q197R (on ENST00000241051 / NM_001077242.2; = p.Q188R on NM_139160.2) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99572587; called by muse, mutect2
- DEPP1 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 21/134 reads (16%) | catalogued as COSV100024348, COSV53575124; called by muse, mutect2, varscan2
- DEPTOR | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV99637928; called by muse, mutect2
- DHX32 | c.1987G>C p.E663Q | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs377344904; called by muse, mutect2, varscan2
- DIDO1 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs767565758, COSV99824924; called by muse, mutect2, varscan2
- DIP2A | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs759704111, COSV59475369; called by muse, mutect2, varscan2
- DISP1 | c.1193G>C p.C398S | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99450104; called by muse, mutect2, varscan2
- DLEC1 | c.3731C>A p.S1244Y | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.231); catalogued as COSV100341595; called by muse, mutect2, varscan2
- DLG5 | c.4553G>C p.G1518A | Missense Mutation (SNP) | VAF 48/293 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100967280; called by muse, mutect2, varscan2
- DMD | c.4698G>T p.L1566F | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as COSV100818398; called by muse, mutect2, varscan2
- DNAH10 | c.8942T>G p.V2981G (on ENST00000409039; = p.V2920G on NM_207437.3) | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV101292020; called by muse, mutect2, varscan2
- DNAH10 | c.13273G>C p.D4425H (on ENST00000409039; = p.D4364H on NM_207437.3) | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV99435244; called by muse, mutect2, varscan2
- DNAH3 | c.3606C>A p.C1202* | Nonsense Mutation (SNP) | VAF 32/173 reads (18%) | catalogued as COSV99765258; called by muse, mutect2, varscan2
- DNAH5 | c.10642A>C p.K3548Q | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.056); catalogued as COSV99445631; called by muse, mutect2, varscan2
- DNAH5 | c.539G>T p.S180I | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.078); catalogued as COSV99445634; called by muse, mutect2, varscan2
- DNAH7 | c.4150A>G p.R1384G | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100414040; called by muse, mutect2, varscan2
- DNAJC6 | c.1486G>T p.D496Y | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV54772913, COSV99674111; called by muse, mutect2, varscan2
- DOCK11 | c.2243A>C p.Q748P | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as COSV99353033; called by muse, mutect2, varscan2
- DPPA3 | c.107C>A p.T36K | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.132); catalogued as rs1482329730, COSV100559824; called by muse, mutect2, varscan2
- DPYD | c.2086C>G p.R696G | Missense Mutation (SNP) | VAF 73/281 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.823); catalogued as COSV100928742; called by muse, mutect2, varscan2
- DROSHA | c.2695C>A p.H899N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100757495, COSV60783189; called by muse, mutect2, varscan2
- DSCAML1 | c.3717C>G p.S1239R (on ENST00000321322; = p.S1179R on NM_020693.4) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100354811; called by muse, mutect2
- DSCC1 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.173); catalogued as COSV100558259; called by muse, mutect2, varscan2
- DUOX2 | c.4054G>A p.G1352S | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.044); catalogued as rs1369160102, COSV101199585; called by muse, mutect2, varscan2
- DUS1L | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 44/238 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV100152400; called by muse, mutect2, varscan2
- DYSF | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | catalogued as COSV99244689; called by muse, mutect2, varscan2
- EGFLAM | c.650G>T p.R217M | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV59303503; called by muse, mutect2, varscan2
- EMSY | c.2120A>G p.Q707R | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.043); catalogued as COSV100595443; called by muse, mutect2, varscan2
- ENPEP | c.1219G>C p.D407H | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV99487137; called by muse, mutect2, varscan2
- ENPP2 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99307608; called by muse, mutect2, varscan2
- EPB42 | c.139G>C p.A47P (on ENST00000441366 / NM_001114134.2; = p.A77P on NM_000119.3) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs778167162, COSV100281808, COSV55749108; called by muse, mutect2, varscan2
- EPS15 | c.502-2A>T p.X168_splice | Splice Site (SNP) | VAF 18/85 reads (21%) | catalogued as COSV100869049; called by muse, mutect2, varscan2
- ERBB3 | c.2838G>A p.K946= | Splice Region (SNP) | VAF 32/98 reads (33%) | catalogued as COSV99915978; called by muse, mutect2, varscan2
- ERP29 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV99923540; called by muse, mutect2, varscan2
- FADD | c.562A>T p.N188Y | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV100096482; called by muse, mutect2, varscan2
- FAM193A | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.311); catalogued as COSV100218650; called by muse, mutect2, varscan2
- FAM3B | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.018); catalogued as COSV100783715, COSV63613665; called by muse, mutect2, varscan2
- FAM47A | c.2238G>T p.K746N | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100649747, COSV60496724, COSV60498855; called by muse, mutect2, varscan2
- FASTK | c.323A>C p.K108T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99879562; called by muse, mutect2
- FAT3 | c.1190T>C p.I397T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as COSV99962540; called by muse, mutect2, varscan2
- FBH1 | c.911C>T p.P304L (on ENST00000362091 / NM_178150.3; = p.P355L on NM_032807.4) | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as rs184032310, COSV62982170; called by muse, mutect2, varscan2
- FBN2 | c.4564G>T p.E1522* | Nonsense Mutation (SNP) | VAF 29/102 reads (28%) | catalogued as COSV99325323; called by muse, mutect2, varscan2
- FEZF1 | c.785G>T p.C262F | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100484415; called by muse, mutect2, varscan2
- FLCN | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs774491699, COSV99550145; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLRT2 | c.880G>T p.G294W | Missense Mutation (SNP) | VAF 63/321 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58145018; called by muse, mutect2, varscan2
- FLT1 | c.3953T>C p.I1318T | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs779884235, COSV99148690; called by muse, mutect2, varscan2
- GABRB1 | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV99780376; called by muse, mutect2, varscan2
- GABRB1 | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV54972443, COSV54998360; called by muse, mutect2, varscan2
- GABRG1 | c.987T>A p.Y329* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as COSV99777484; called by muse, mutect2, varscan2
- GALK2 | c.481G>T p.V161L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100508637; called by muse, mutect2, varscan2
- GGCX | c.665A>G p.D222G | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1334688952, COSV99289665; called by muse, mutect2, varscan2
- GIT2 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as rs766905782, COSV100188842; called by muse, mutect2, varscan2
- GPATCH2 | c.1031G>T p.R344I | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs991212267, COSV100861346, COSV100861352, COSV100861383; called by muse, mutect2, varscan2
- GPR162 | c.715T>G p.F239V | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV99163695; called by muse, mutect2, varscan2
- GRIA2 | c.1333T>C p.Y445H | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.501); catalogued as COSV99643191; called by muse, mutect2, varscan2
- GRID1 | c.2719G>A p.G907S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV100022197; called by muse, mutect2, varscan2
- GRIK2 | c.2310G>T p.M770I | Missense Mutation (SNP) | VAF 95/181 reads (52%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs745663188, COSV59762554; called by muse, mutect2, varscan2
- GRK5 | c.1390C>A p.P464T | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV100962850, COSV64865600; called by muse, mutect2, varscan2
- GRM8 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 35/94 reads (37%) | catalogued as COSV100281060; called by muse, mutect2, varscan2
- GUCY2C | c.2333T>A p.L778Q | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99663281; called by muse, mutect2, varscan2
- GUK1 | c.476-1G>T p.X159_splice | Splice Site (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100451622; called by muse, mutect2, varscan2
- HAPLN3 | c.19G>T p.V7F | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100613618; called by muse, mutect2
- HEPACAM | c.601G>C p.V201L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs1405884792, COSV100005482; called by muse, mutect2, varscan2
- HEPH | c.22T>C p.W8R (on ENST00000343002; = p.W62R on NM_138737.5) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as rs764956281, COSV100294215; called by muse, varscan2
- HFM1 | c.1804T>C p.F602L | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99645461; called by muse, mutect2, varscan2
- HLA-A | c.443T>A p.I148N | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100954318; called by muse, mutect2, varscan2
- HMMR | c.146-1G>A p.X49_splice | Splice Site (SNP) | VAF 22/82 reads (27%) | catalogued as COSV100243731, COSV57085555; called by muse, mutect2, varscan2
- HOPX | c.209C>T p.S70F (on ENST00000317745; = p.S88F on NM_032495.6) | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58499806; called by muse, mutect2, varscan2
- HOXC8 | c.239G>T p.S80I | Missense Mutation (SNP) | VAF 77/355 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV104377814, COSV99236662; called by muse, mutect2, varscan2
- HOXD3 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.431); catalogued as COSV99979917; called by muse, mutect2, varscan2
- HSF5 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.682); catalogued as COSV100089878; called by muse, mutect2, varscan2
- HSPA8 | c.916A>G p.N306D | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated, low confidence (0.59); PolyPhen probably damaging (0.953); catalogued as COSV99914230; called by muse, mutect2, varscan2
- IL1RAPL1 | c.2048C>T p.P683L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100145409; called by muse, mutect2, varscan2
- IL27RA | c.730G>T p.G244W | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV99651962; called by muse, mutect2, varscan2
- IL31RA | c.1902G>T p.K634N | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.895); catalogued as COSV100732468; called by muse, mutect2, varscan2
- IMPG2 | c.2915C>T p.P972L | Missense Mutation (SNP) | VAF 82/215 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as rs1205331271, COSV51987548, COSV99515897; called by muse, mutect2, varscan2
- ITGB1BP2 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99338611; called by muse, varscan2
- ITPR2 | c.6652G>A p.A2218T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV101189838; called by muse, mutect2, varscan2
- IZUMO1R | c.343C>A p.Q115K (on ENST00000440961; = p.Q122K on NM_001199206.3) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100126815; called by muse, mutect2, varscan2
- KCNK4 | c.1097G>C p.R366T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV60453809; called by muse, mutect2, varscan2
- KCNK6 | c.386T>A p.L129Q | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99649275; called by muse, mutect2, varscan2
- KDR | c.2389C>A p.L797M | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.29); catalogued as COSV99816826; called by muse, mutect2, varscan2
- KIAA1522 | c.1553C>G p.T518R (on ENST00000373480 / NM_001198972.2; = p.T577R on NM_020888.3) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776048847, COSV99614188; called by mutect2, varscan2
- KIF21B | c.1303C>T p.R435W | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs755226578, COSV100143805; called by muse, mutect2, varscan2
- KLHL4 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV100909159; called by muse, mutect2, varscan2
- KLK5 | c.672G>C p.Q224H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.884); catalogued as COSV100306899; called by muse, mutect2, varscan2
- KLRC3 | c.465T>A p.C155* | Nonsense Mutation (SNP) | VAF 48/240 reads (20%) | catalogued as COSV101122890; called by muse, mutect2, varscan2
- KMT2C | c.1185-1G>T p.X395_splice | Splice Site (SNP) | VAF 31/128 reads (24%) | catalogued as COSV100067914, COSV51503028; called by muse, mutect2, varscan2
- KRT72 | c.642-1G>T p.X214_splice | Splice Site (SNP) | VAF 21/72 reads (29%) | catalogued as COSV99537086; called by muse, mutect2, varscan2
- KY | c.1981C>A p.Q661K | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.12); catalogued as COSV101414950, COSV101414983; called by muse, mutect2, varscan2
- LCE5A | c.47G>A p.C16Y | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV100524171; called by muse, mutect2, varscan2
- LCOR | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99616626; called by muse, mutect2, varscan2
- LDB2 | c.166A>T p.T56S | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.997); catalogued as COSV100452729; called by muse, mutect2, varscan2
- LDHAL6B | c.706G>T p.G236* | Nonsense Mutation (SNP) | VAF 25/130 reads (19%) | catalogued as COSV99894575; called by muse, mutect2, varscan2
- LGR6 | c.1672C>G p.L558V (on ENST00000367278 / NM_001017403.1; = p.L506V on NM_021636.3) | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99706166; called by muse, varscan2
- LILRB2 | c.917G>T p.C306F | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs752287398; called by muse, mutect2, varscan2
- LIN28A | c.479A>C p.K160T | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99575223; called by muse, mutect2, varscan2
- LIN28B | c.118C>A p.R40S | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV100558571; called by muse, mutect2, varscan2
- LMLN | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 12/70 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV54563254, COSV99502096; called by muse, mutect2, varscan2
- LONP2 | c.1772G>T p.R591L | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV53526621, COSV99588905; called by muse, mutect2, varscan2
- LPA | c.4869T>A p.S1623R | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.611); catalogued as COSV100306217; called by muse, mutect2, varscan2
- LRRC4C | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV53437898, COSV99538561; called by muse, mutect2, varscan2
- LRRK1 | c.1420-2A>C p.X474_splice | Splice Site (SNP) | VAF 24/162 reads (15%) | catalogued as COSV99437963; called by muse, mutect2, varscan2
- LZTS1 | c.290A>T p.D97V | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99742710; called by muse, mutect2, varscan2
- MAGEA10 | c.1054A>T p.T352S | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99726594; called by muse, mutect2, varscan2
- MAGEA3 | c.250T>A p.Y84N | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100938999; called by muse, mutect2, varscan2
- MAGEF1 | c.168del p.G58Afs*19 | Frame Shift Del (DEL) | VAF 9/84 reads (11%) | catalogued as COSV100510899; called by mutect2, pindel
- MAP2 | c.1040C>A p.P347Q | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV99558139; called by muse, mutect2, varscan2
- ME2 | c.1041T>G p.Y347* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100360663; called by muse, mutect2, varscan2
- MFN1 | c.556A>G p.T186A | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.389); catalogued as COSV99764225; called by muse, mutect2, varscan2
- MGAT4C | c.348A>T p.L116F | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100152710; called by muse, mutect2, varscan2
- MMP12 | c.772A>G p.I258V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV100404826; called by muse, mutect2
- MMP15 | c.359del p.R120Qfs*2 | Frame Shift Del (DEL) | VAF 58/166 reads (35%) | catalogued as COSV54679069, COSV54679974; called by mutect2, pindel, varscan2
- MMP9 | c.1066A>T p.K356* | Nonsense Mutation (SNP) | VAF 34/181 reads (19%) | catalogued as COSV100812355; called by muse, mutect2, varscan2
- MMRN2 | c.400+1G>T p.X134_splice | Splice Site (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100922507; called by muse, mutect2
- MORC1 | c.826T>A p.Y276N | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99225238; called by muse, mutect2, varscan2
- MRGPRX3 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 52/264 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as rs772433034, COSV101283498; called by muse, mutect2, varscan2
- MRPL46 | c.799A>G p.K267E | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs749527129, COSV100428683; called by muse, mutect2, varscan2
- MRTFB | c.652A>C p.S218R | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.289); catalogued as COSV100370885; called by muse, mutect2, varscan2
- MS4A13 | c.349G>T p.G117C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV100981042, COSV65445673; called by muse, mutect2, varscan2
- MSS51 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100200086, COSV99072345; called by muse, mutect2, varscan2
- MTF1 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs772009543, COSV100888579; called by muse, mutect2, varscan2
- MYO18A | c.3413G>C p.R1138P | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.405); catalogued as COSV100571969; called by muse, mutect2, varscan2
- MYO5B | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99543775; called by muse, mutect2, varscan2
- MYO7A | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV101289052; called by muse, mutect2, varscan2
- MYT1L | c.2558G>C p.R853P | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV101219097, COSV67726880; called by muse, mutect2, varscan2
- NACA2 | c.460C>A p.Q154K | Missense Mutation (SNP) | VAF 74/367 reads (20%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.9); catalogued as rs76240935, COSV101478546; called by muse, mutect2, varscan2
- NAV3 | c.6007T>A p.C2003S (on ENST00000397909 / NM_001024383.2; = p.C1981S on NM_014903.6) | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as COSV99887398; called by muse, mutect2, varscan2
- NAV3 | c.6104C>T p.P2035L (on ENST00000397909 / NM_001024383.2; = p.P2013L on NM_014903.6) | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99887403; called by muse, mutect2, varscan2
- NCAPD3 | c.4289G>C p.S1430T | Missense Mutation (SNP) | VAF 52/275 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100137866; called by muse, mutect2, varscan2
- NEB | c.12915G>T p.M4305I | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99415712; called by muse, mutect2, varscan2
- NECTIN1 | c.1004-1G>A p.X335_splice | Splice Site (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99871821; called by muse, mutect2, varscan2
- NECTIN4 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs773060708, COSV100919833, COSV63513312; called by muse, mutect2, varscan2
- NELL1 | c.1432G>T p.D478Y | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV54244136, COSV54248983; called by muse, mutect2, varscan2
- NLRP1 | c.3365C>T p.A1122V | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as rs530274359, COSV52572296; called by muse, mutect2, varscan2
- NLRP11 | c.2070C>A p.S690R | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV100789643; called by muse, mutect2, varscan2
- NMUR2 | c.925C>T p.H309Y | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150236745, COSV54921872; called by muse, mutect2, varscan2
- NOSIP | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.411); catalogued as rs770835468, COSV100182141; called by muse, mutect2, varscan2
- NPM3 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV100761666, COSV63381971; called by muse, mutect2, varscan2
- NRG3 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100931199; called by muse, mutect2
- NRXN1 | c.2398G>A p.A800T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as COSV99044236; called by muse, mutect2, varscan2
- NSD1 | c.5272del p.E1758Rfs*5 | Frame Shift Del (DEL) | VAF 31/149 reads (21%) | catalogued as COSV61778689; called by mutect2, pindel, varscan2
- NTRK3 | c.1101G>T p.K367N | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV100445661; called by muse, mutect2, varscan2
- NXPE1 | c.1456G>C p.E486Q (on ENST00000424269; = p.E344Q on NM_152315.5) | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV99319983; called by muse, mutect2, varscan2
- NYAP2 | c.837G>T p.L279F | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.391); catalogued as COSV99795887; called by muse, mutect2, varscan2
- OAS3 | c.2954A>C p.K985T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.085); catalogued as COSV57447415, COSV99966107; called by muse, mutect2, varscan2
- ODF4 | c.575T>C p.L192P | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1198836144, COSV100071809; called by muse, mutect2, varscan2
- OOSP2 | c.63T>C p.H21= | Splice Region (SNP) | VAF 35/137 reads (26%) | catalogued as COSV99613149; called by muse, mutect2, varscan2
- OR10A5 | c.661C>A p.R221S | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.5); catalogued as rs776925337, COSV100203376; called by muse, mutect2, varscan2
- OR10G9 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100901483; called by muse, mutect2, varscan2
- OR11H1 | c.55C>A p.Q19K | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV99421608; called by muse, mutect2, varscan2
- OR1C1 | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.407); catalogued as COSV101376188; called by muse, mutect2, varscan2
- OR2A12 | c.817C>A p.L273I | Missense Mutation (SNP) | VAF 117/470 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.718); catalogued as COSV101283150, COSV68821183; called by muse, mutect2, varscan2
- OR2F1 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 52/336 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs141187562; called by muse, mutect2, varscan2
- OR2J2 | c.698C>T p.T233I | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as rs996545889, COSV101013296; called by muse, mutect2, varscan2
- OR51S1 | c.188T>A p.L63Q | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100437357; called by muse, mutect2, varscan2
- OR52L1 | c.913C>A p.L305I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV100176052; called by muse, mutect2
- OR52N1 | c.386G>T p.C129F | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100398610; called by muse, mutect2, varscan2
- OR5K3 | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 67/439 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV101051614; called by muse, mutect2, varscan2
- OR5K4 | c.128T>A p.L43H | Missense Mutation (SNP) | VAF 82/437 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100721304; called by muse, mutect2, varscan2
- OR8B2 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.692); catalogued as rs1185586244, COSV100899327; called by muse, varscan2
- OSR1 | c.403G>T p.G135C | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as rs975152724, COSV99693546; called by muse, mutect2, varscan2
- OTOP1 | c.1697G>T p.R566L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV56390561, COSV56392886, COSV99587400; called by muse, mutect2, varscan2
- PABPC3 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs200924407, COSV99879076; called by muse, mutect2, varscan2
- PACRG | c.788T>A p.L263* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | catalogued as COSV100433345; called by muse, mutect2, varscan2
- PAPPA2 | c.5218G>A p.G1740S | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100867622; called by muse, mutect2, varscan2
- PARD3 | c.2751A>C p.R917S | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100400368; called by muse, mutect2, varscan2
- PARP8 | c.1742A>T p.Y581F | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.931); catalogued as COSV99890168; called by muse, mutect2, varscan2
- PCDH15 | c.4383C>G p.Y1461* | Nonsense Mutation (SNP) | VAF 23/95 reads (24%) | catalogued as rs1033803342, COSV100216029, COSV57379086; called by muse, mutect2, varscan2
- PCDH7 | c.946G>T p.D316Y | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100687626, COSV100688834; called by muse, mutect2, varscan2
- PCDHA4 | c.2363C>G p.T788R | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV100793183; called by muse, mutect2, varscan2
- PCDHA8 | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.323); catalogued as rs1554139566, COSV100969510, COSV65324504, COSV65330213; called by muse, mutect2, varscan2
- PCDHAC1 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs782636217, COSV99165112; called by muse, mutect2, varscan2
- PCDHB11 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.035); catalogued as rs201116406; called by muse, mutect2, varscan2
- PCDHB14 | c.1325C>G p.S442C | Missense Mutation (SNP) | VAF 59/257 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as COSV99505589; called by muse, mutect2, varscan2
- PCDHGA1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 67/281 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.049); catalogued as COSV100965935; called by muse, mutect2, varscan2
- PCDHGA8 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99531913; called by mutect2, varscan2
- PCDHGA8 | c.2185G>T p.G729C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as rs774774010, COSV99531916; called by muse, mutect2, varscan2
- PCSK2 | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 51/245 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99358799; called by muse, mutect2, varscan2
- PCSK5 | c.4861C>T p.H1621Y | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV101377285, COSV70451349; called by muse, mutect2, varscan2
- PCSK5 | c.4862A>C p.H1621P | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV101377287; called by muse, mutect2, varscan2
- PDGFC | c.709G>C p.D237H | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV99924832; called by muse, mutect2, varscan2
- PDGFRA | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs587778598, COSV57265859; ClinVar: likely benign / uncertain significance / not provided; called by muse, mutect2, varscan2
- PEX5L | c.281T>A p.I94K | Missense Mutation (SNP) | VAF 65/319 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99828007; called by muse, mutect2, varscan2
- PGBD2 | c.1706A>G p.Q569R | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as COSV100251871; called by muse, mutect2, varscan2
- PGM1 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as rs201303497, COSV64301589; called by muse, mutect2, varscan2
- PHF12 | c.1097G>T p.R366L | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV99255497; called by muse, mutect2, varscan2
- PKHD1 | c.6892A>T p.R2298* | Nonsense Mutation (SNP) | VAF 29/131 reads (22%) | catalogued as COSV100581365; called by muse, mutect2, varscan2
- PLA2G2D | c.430G>C p.G144R | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100907998; called by muse, mutect2, varscan2
- PLCB4 | c.2336A>G p.N779S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as COSV99594547; called by muse, mutect2, varscan2
- PLCG2 | c.914A>C p.K305T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV100842082; called by muse, mutect2, varscan2
- PLEKHG3 | c.2792C>G p.S931C (on ENST00000394691; = p.S987C on NM_001308147.2) | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV55980069, COSV99906303; called by muse, mutect2, varscan2
- PLSCR2 | c.453G>C p.R151S (on ENST00000497985 / NM_001199978.1; = p.R78S on NM_020359.2) | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.743); catalogued as COSV100367619, COSV60862560; called by muse, mutect2, varscan2
- PLXNA4 | c.1675G>T p.V559F | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100322700; called by muse, mutect2, varscan2
- POLI | c.349G>T p.V117L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as rs142974796, COSV99470863; called by muse, mutect2, varscan2
- POLR1C | c.959T>A p.V320E | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.074); catalogued as COSV99540480; called by muse, mutect2, varscan2
- PPL | c.1954G>T p.G652W | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as COSV100630528; called by muse, mutect2
- PPP1R9A | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99194670; called by muse, mutect2, varscan2
- PPP2R3A | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.401); catalogued as COSV99386536; called by muse, mutect2, varscan2
- PPRC1 | c.3611G>C p.G1204A | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV99531343; called by muse, mutect2, varscan2
- PRDM14 | c.876A>T p.E292D | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); catalogued as COSV99399908; called by muse, mutect2, varscan2
- PRDM9 | c.1096G>A p.G366S | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99689857; called by muse, mutect2, varscan2
- PRKCG | c.556A>G p.M186V | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV99668583; called by muse, mutect2, varscan2
- PRKD1 | c.1573G>T p.G525C | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100119413; called by muse, mutect2, varscan2
- PRMT9 | c.1502G>T p.S501I | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV100482018; called by muse, mutect2, varscan2
- PRPF6 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 67/272 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53866477; called by muse, mutect2, varscan2
- PRRC2B | c.3985G>T p.E1329* | Nonsense Mutation (SNP) | VAF 28/114 reads (25%) | catalogued as COSV100621501; called by muse, mutect2, varscan2
- PRUNE2 | c.5293G>T p.D1765Y | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100944254, COSV100944652, COSV65037554; called by muse, mutect2
- PTGER3 | c.641G>T p.R214L | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV100138364, COSV60689639; called by muse, mutect2, varscan2
- PTGER4 | c.784C>A p.R262S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV100201428; called by muse, mutect2, varscan2
- PTPN3 | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 51/140 reads (36%) | catalogued as COSV99355418, COSV99356516; called by muse, mutect2, varscan2
- PTPRM | c.538C>A p.H180N | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV100155304; called by muse, mutect2, varscan2
- PYDC2 | c.57C>A p.S19R | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.448); catalogued as COSV101573347; called by muse, mutect2, varscan2
- PYGL | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM117185, COSV99368294; called by muse, mutect2, varscan2
- RAF1 | c.207+1G>A p.X69_splice | Splice Site (SNP) | VAF 28/86 reads (33%) | catalogued as rs772835401, COSV99311976; called by muse, mutect2, varscan2
- RALGAPB | c.3686G>A p.G1229E | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53436822; called by muse, mutect2, varscan2
- RBM46 | c.311C>G p.A104G | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.593); catalogued as COSV99907903; called by muse, mutect2, varscan2
- REG1B | c.60C>A p.S20R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.445); catalogued as COSV100521278; called by muse, mutect2, varscan2
- RFPL2 | c.493A>C p.K165Q | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV99964065; called by muse, mutect2, varscan2
- RFX4 | c.1076C>A p.T359N (on ENST00000392842 / NM_213594.3; = p.T265N on NM_032491.6) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.543); catalogued as COSV99985428; called by muse, mutect2, varscan2
- RNF121 | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100683459; called by muse, mutect2, varscan2
- RNF145 | c.1403G>C p.C468S (on ENST00000424310 / NM_001199383.2; = p.C496S on NM_144726.2) | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.406); catalogued as COSV99193264; called by muse, mutect2, varscan2
- ROBO2 | c.68G>C p.R23P | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100164581, COSV100169949; called by muse, mutect2, varscan2
- ROR1 | c.1766A>T p.H589L | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.115); catalogued as COSV100934974; called by muse, mutect2, varscan2
- RPL10L | c.90G>C p.K30N | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV100022410; called by muse, mutect2, varscan2
- RPP38 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV100975471; called by muse, mutect2, varscan2
- RPS6KA2 | c.975G>C p.T325= | Splice Region (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99690282; called by muse, mutect2, varscan2
- RRH | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 54/251 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.068); catalogued as COSV100495984; called by muse, mutect2, varscan2
- RSAD2 | c.363C>A p.N121K | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101149775; called by muse, mutect2, varscan2
- SAAL1 | c.161C>A p.S54Y | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.742); catalogued as COSV100253756; called by muse, mutect2, varscan2
- SALL1 | c.3270C>G p.N1090K | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV99171601; called by muse, varscan2
- SALL1 | c.3203G>A p.G1068D | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV99171605; called by muse, varscan2
- SAT2 | c.486G>C p.E162D | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99352114; called by muse, mutect2, varscan2
- SCARF1 | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs768343153, COSV99556900; called by muse, mutect2, varscan2
- SCG2 | c.1786T>C p.Y596H | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1302113158, COSV100544606; called by muse, mutect2, varscan2
- SCN1A | c.5636G>A p.S1879N (on ENST00000303395 / NM_001202435.3; = p.S1868N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs112244937, COSV100319472; called by muse, mutect2, varscan2
- SEMA3D | c.1477G>T p.V493L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99405947; called by muse, mutect2, varscan2
- SERPINA12 | c.68C>A p.P23Q | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV100369590, COSV57944173; called by muse, mutect2, varscan2
- SERPINA5 | c.505A>T p.M169L | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100291486; called by muse, mutect2, varscan2
- SH2D4A | c.281G>T p.C94F | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99744290; called by muse, mutect2, varscan2
- SH3BP5L | c.665G>C p.S222T | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV100821971, COSV63538711; called by muse, mutect2, varscan2
- SH3TC2 | c.3563G>T p.C1188F | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.937); catalogued as COSV100101273; called by muse, mutect2, varscan2
- SI | c.5197+1G>T p.X1733_splice | Splice Site (SNP) | VAF 25/141 reads (18%) | catalogued as rs754538482, COSV100014239; called by muse, mutect2, varscan2
- SI | c.4118G>T p.W1373L | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100014243, COSV100016676; called by muse, mutect2, varscan2
- SIAH3 | c.60G>C p.Q20H | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV101247702, COSV68551612; called by muse, mutect2, varscan2
- SIRT1 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99281613; called by muse, mutect2, varscan2
- SLAIN2 | c.616A>C p.S206R | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99971511; called by muse, mutect2, varscan2
- SLAMF6 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 57/397 reads (14%) | catalogued as COSV100924834, COSV63587984; called by muse, mutect2, varscan2
- SLC12A9 | c.179T>C p.I60T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as rs371310415; called by mutect2, varscan2
- SLC13A3 | c.921-1G>A p.X307_splice | Splice Site (SNP) | VAF 29/110 reads (26%) | catalogued as COSV99286246; called by muse, mutect2, varscan2
- SLC16A6 | c.531T>G p.I177M | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV100517197; called by muse, mutect2
- SLC17A8 | c.1422C>A p.H474Q | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV100035233; called by muse, mutect2, varscan2
- SLC2A14 | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.515); catalogued as COSV100533574, COSV61585766; called by muse, mutect2, varscan2
- SLC37A2 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100016954, COSV53520614; called by muse, mutect2, varscan2
- SLC4A3 | c.422A>T p.E141V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.368); catalogued as COSV99812482; called by muse, mutect2, varscan2
- SLC4A5 | c.2957T>G p.L986R | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.077); catalogued as COSV100697436; called by muse, mutect2, varscan2
- SLC4A8 | c.1347G>C p.G449= | Splice Region (SNP) | VAF 11/87 reads (13%) | catalogued as COSV100176503; called by muse, mutect2, varscan2
- SLCO2A1 | c.963G>T p.R321S | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as rs773913925, COSV100188689; called by muse, mutect2, varscan2
- SLFN12 | c.1333C>T p.L445F | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100512930; called by muse, mutect2, varscan2
- SLITRK4 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV100567175; called by muse, mutect2, varscan2
- SMC4 | c.484G>T p.V162F | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100424444; called by muse, mutect2, varscan2
- SMG6 | c.1310G>C p.G437A | Missense Mutation (SNP) | VAF 58/256 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.866); catalogued as rs923802783, COSV53962944, COSV99557830; called by muse, mutect2, varscan2
- SNAPC4 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs372524659, COSV100046856; called by muse, mutect2, varscan2
- SNRNP40 | c.918C>T p.D306= | Splice Region (SNP) | VAF 26/118 reads (22%) | catalogued as rs1246224803, COSV99745088; called by muse, mutect2, varscan2
- SNX32 | c.877C>G p.L293V | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV100362568, COSV57450040; called by muse, mutect2, varscan2
- SOD3 | c.314A>T p.E105V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV101181071; called by muse, mutect2
- SORCS1 | c.1306T>A p.Y436N | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99543786; called by muse, mutect2, varscan2
- SORCS3 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1321628534, COSV100864694; called by muse, mutect2, varscan2
- SORL1 | c.5417A>G p.K1806R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99492990; called by muse, mutect2, varscan2
- SOS1 | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 59/296 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as rs373898570; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPAG11B | c.254G>T p.R85M | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99872776; called by muse, mutect2, varscan2
- SPATA31E1 | c.2039C>A p.P680H | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV100349985; called by muse, mutect2
- SPATA31E1 | c.4257G>T p.R1419S | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.556); catalogued as COSV100349989; called by muse, mutect2, varscan2
- SPTA1 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.026); catalogued as COSV63749229, COSV63754817; called by muse, mutect2, varscan2
- SPTBN1 | c.1817C>A p.P606H | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100441912; called by muse, mutect2, varscan2
- SRGAP1 | c.1183G>T p.D395Y | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100754314, COSV61898845; called by muse, mutect2, varscan2
- SSBP2 | c.334G>C p.G112R | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100283101; called by muse, mutect2, varscan2
- SSUH2 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.07); catalogued as rs767428753, COSV58031755; called by muse, mutect2, varscan2
- STAMBPL1 | c.128G>T p.S43I | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV100905076; called by muse, mutect2, varscan2
- STARD13 | c.1169A>T p.Q390L (on ENST00000336934 / NM_001243476.3; = p.Q272L on NM_052851.3) | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV99715507; called by muse, mutect2, varscan2
- STRADA | c.220G>T p.V74L (on ENST00000336174 / NM_001363786.1; = p.V37L on NM_153335.6) | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99834926; called by muse, mutect2, varscan2
- SV2C | c.672C>A p.C224* | Nonsense Mutation (SNP) | VAF 73/402 reads (18%) | catalogued as COSV100455712; called by muse, mutect2, varscan2
- SVIL | c.2137G>A p.V713I (on ENST00000355867 / NM_021738.3; = p.V319I on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV100880967; called by muse, varscan2
- SYNPO2 | c.596T>A p.L199Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100204985; called by muse, mutect2, varscan2
- SYT7 | c.425G>T p.S142I | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99801170; called by muse, mutect2, varscan2
- TACC2 | c.6635G>T p.G2212V (on ENST00000334433; = p.G290V on NM_006997.4) | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99586674; called by muse, mutect2, varscan2
- TACR3 | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 25/104 reads (24%) | catalogued as COSV59210057; called by muse, mutect2, varscan2
- TANGO6 | c.2850G>A p.M950I | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV99935745; called by muse, mutect2, varscan2
- TBC1D32 | c.2094A>T p.Q698H | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as COSV99249623; called by muse, mutect2, varscan2
- TCHH | c.3644G>A p.R1215Q | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); catalogued as rs1264182718, COSV100914913; called by muse, mutect2, varscan2
- TECTA | c.474C>A p.S158R | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99878805; called by muse, mutect2, varscan2
- TFAP2D | c.502C>A p.L168M | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV99145705; called by muse, mutect2, varscan2
- TFE3 | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as COSV100252368, COSV59946503; called by muse, mutect2, varscan2
- TFRC | c.472G>T p.G158* | Nonsense Mutation (SNP) | VAF 33/148 reads (22%) | catalogued as COSV100786393; called by muse, mutect2, varscan2
- TGM1 | c.2088G>C p.T696= | Splice Region (SNP) | VAF 17/88 reads (19%) | catalogued as COSV99252808; called by muse, mutect2, varscan2
- THBS2 | c.3465C>A p.F1155L | Missense Mutation (SNP) | VAF 50/375 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100827644; called by muse, mutect2, varscan2
- THSD7B | c.2846G>T p.G949V | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55726618, COSV55753571; called by muse, mutect2, varscan2
- TIGD3 | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99361370; called by muse, mutect2, varscan2
- TKTL2 | c.427C>A p.L143I | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.314); catalogued as COSV99761142; called by muse, mutect2, varscan2
- TMEM132B | c.1538G>T p.W513L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100168429, COSV100168711; called by muse, mutect2, varscan2
- TMEM132B | c.1539G>T p.W513C | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100168425; called by muse, mutect2, varscan2
- TMEM184B | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as rs1156630982, COSV62674004; called by muse, mutect2, varscan2
- TNN | c.640C>A p.R214S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as COSV53425645, COSV99511214; called by muse, mutect2, varscan2
- TRABD2A | c.371A>G p.K124R | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100119656; called by muse, mutect2, varscan2
- TRAFD1 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.965); catalogued as COSV99986796; called by muse, mutect2, varscan2
- TRBV27 | c.55del p.L19Wfs*5 | Frame Shift Del (DEL) | VAF 10/89 reads (11%) | catalogued as rs760901905; called by mutect2, pindel, varscan2
- TRIM36 | c.115C>A p.L39M | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.781); catalogued as COSV99142266; called by muse, mutect2, varscan2
- TRIM9 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.546); catalogued as COSV100030663; called by muse, mutect2, varscan2
- TRIP11 | c.1910G>A p.S637N | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99970373; called by muse, mutect2, varscan2
- TRPC1 | c.1316T>G p.I439S (on ENST00000476941 / NM_001251845.2; = p.I405S on NM_003304.4) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV99858289; called by muse, varscan2
- TRPM3 | c.764C>A p.P255H (on ENST00000357533 / NM_001366142.2; = p.P100H on NM_020952.6) | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100624146; called by muse, mutect2, varscan2
- TRRAP | c.10999A>T p.T3667S (on ENST00000359863 / NM_001244580.1; = p.T3638S on NM_003496.3) | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as COSV100705366; called by muse, mutect2, varscan2
- TTN | c.74854G>A p.D24952N (on ENST00000591111; = p.D17528N on NM_003319.4) | Missense Mutation (SNP) | VAF 59/264 reads (22%) | PolyPhen benign (0.369); catalogued as COSV100596632; called by muse, mutect2, varscan2
- TTN | c.21076C>G p.Q7026E (on ENST00000591111; = p.Q6099E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | PolyPhen benign (0.001); catalogued as COSV100596635; called by muse, mutect2, varscan2
- TTN | c.13262G>A p.R4421Q (on ENST00000591111; = p.R4375Q on NM_003319.4) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | PolyPhen benign (0.048); catalogued as rs553541436, COSV60462550; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.9003G>T p.W3001C (on ENST00000591111; = p.W2955C on NM_003319.4) | Missense Mutation (SNP) | VAF 17/102 reads (17%) | PolyPhen probably damaging (0.999); catalogued as COSV100596639; called by muse, mutect2, varscan2
- TTN | c.4316C>A p.P1439H (on ENST00000591111; = p.P1393H on NM_003319.4) | Missense Mutation (SNP) | VAF 27/97 reads (28%) | PolyPhen probably damaging (0.999); catalogued as COSV100596642; called by muse, mutect2, varscan2
- TYR | c.833G>C p.R278P | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.856); catalogued as COSV54475107, COSV99633723, COSV99633969; called by muse, mutect2, varscan2
- UBN1 | c.2953G>T p.A985S | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV99277526; called by muse, mutect2, varscan2
- UGDH | c.997A>T p.I333F | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.06); catalogued as COSV100328362, COSV57096828; called by muse, mutect2, varscan2
- UNC79 | c.1064A>G p.E355G (on ENST00000393151 / NM_001346218.2; = p.E178G on NM_020818.5) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99826073; called by muse, mutect2, varscan2
- USH2A | c.3790T>A p.S1264T | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.272); catalogued as COSV56430868; called by muse, mutect2, varscan2
- VEZT | c.289A>G p.T97A | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV99703511; called by muse, mutect2, varscan2
- VIPR2 | c.661C>A p.L221M | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100056652; called by muse, mutect2, varscan2
- VPS13A | c.6131A>C p.Y2044S | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.94); catalogued as COSV100652235; called by muse, mutect2, varscan2
- VPS39 | c.667G>T p.D223Y (on ENST00000348544 / NM_001301138.2; = p.D212Y on NM_015289.5) | Missense Mutation (SNP) | VAF 49/260 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100529004; called by muse, mutect2, varscan2
- WDFY3 | c.8833A>G p.I2945V | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99882279; called by muse, mutect2, varscan2
- WDR17 | c.2231G>T p.W744L | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV99706896; called by muse, mutect2, varscan2
- WDR17 | c.3399A>G p.I1133M | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs1338844292, COSV99706898, COSV99708522; called by muse, mutect2, varscan2
- WDR90 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs377339163; called by muse, mutect2
- WEE2 | c.850C>T p.H284Y | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as COSV101285126; called by muse, mutect2, varscan2
- WRAP73 | c.411G>T p.Q137H | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as COSV99573137; called by muse, mutect2, varscan2
- XRCC1 | c.423del p.F142Lfs*3 | Frame Shift Del (DEL) | VAF 14/71 reads (20%) | catalogued as COSV53448285; called by mutect2, pindel, varscan2
- YTHDC2 | c.3163G>A p.V1055M | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV99362942; called by muse, mutect2, varscan2
- ZBED4 | c.3496T>G p.L1166V | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV99350905; called by muse, mutect2, varscan2
- ZDBF2 | c.3774A>T p.E1258D | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as COSV100984408; called by muse, mutect2, varscan2
- ZFYVE26 | c.1250A>C p.E417A | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV100720122; called by muse, mutect2, varscan2
- ZIC4 | c.934G>C p.D312H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV101267842, COSV67174160; called by muse, mutect2, varscan2
- ZNF142 | c.4645A>G p.K1549E (on ENST00000411696 / NM_001379660.1; = p.K1349E on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV101376904; called by muse, mutect2, varscan2
- ZNF18 | c.512C>G p.S171C | Missense Mutation (SNP) | VAF 75/420 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.137); catalogued as COSV100503038, COSV59550526; called by muse, mutect2, varscan2
- ZNF180 | c.1040A>T p.N347I | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV99659627; called by muse, mutect2, varscan2
- ZNF184 | c.1813A>G p.K605E | Missense Mutation (SNP) | VAF 80/160 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV99279406; called by muse, mutect2, varscan2
- ZNF208 | c.703G>T p.G235C | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101236869; called by muse, mutect2, varscan2
- ZNF287 | c.1499G>C p.R500T | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101209332; called by muse, mutect2, varscan2
- ZNF568 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100451181; called by muse, mutect2, varscan2
- ZNF585B | c.305G>T p.W102L | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV100459319, COSV100459321; called by muse, mutect2, varscan2
- ZNF585B | c.304T>A p.W102R | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs753069441, COSV100459320; called by muse, mutect2, varscan2
- ZNF610 | c.1061G>C p.S354T | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100016717; called by muse, mutect2, varscan2
- ZNF800 | c.1618G>C p.V540L | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV56179939, COSV99757677; called by muse, mutect2, varscan2
- ZSCAN25 | c.822A>T p.E274D | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99500428; called by muse, mutect2, varscan2
- ZSWIM2 | c.441C>A p.C147* | Nonsense Mutation (SNP) | VAF 22/432 reads (5%) | catalogued as COSV99719952; called by muse, mutect2
- ABCB4 | c.301del p.S101Rfs*3 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | called by mutect2, pindel, varscan2
- ADAMTS6 | c.1871G>T p.C624F | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- CABP1 | c.1066del p.D356Mfs*12 (on ENST00000316803 / NM_001033677.1; = p.D153Mfs*12 on NM_004276.5) | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel, varscan2
- DMRT3 | c.925del p.S309Pfs*10 | Frame Shift Del (DEL) | VAF 20/91 reads (22%) | called by mutect2, pindel, varscan2
- DNM2 | c.2333del p.P778Lfs*7 (on ENST00000355667 / NM_001005360.3; = p.P774Lfs*7 on NM_004945.3) | Frame Shift Del (DEL) | VAF 66/204 reads (32%) | called by mutect2, pindel, varscan2
- GTF2IRD2B | c.1304C>G p.A435G | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.9); called by mutect2, varscan2
- HERC2P3 | n.1575-2A>C | Splice Site (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- IGKV1-12 | c.147G>T p.Q49H | Missense Mutation (SNP) | VAF 24/285 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.274); called by muse, mutect2
- IGKV1D-43 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 52/251 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KCNMB3 | c.69del p.T24Qfs*20 | Frame Shift Del (DEL) | VAF 22/140 reads (16%) | called by mutect2, pindel, varscan2
- LSG1 | c.1688del p.Q563Rfs*4 | Frame Shift Del (DEL) | VAF 10/61 reads (16%) | called by mutect2, pindel, varscan2
- LSM14B | c.23dup p.Y9Vfs*41 | Frame Shift Ins (INS) | VAF 8/40 reads (20%) | called by mutect2, varscan2
- MUC7 | c.530del p.P177Qfs*93 | Frame Shift Del (DEL) | VAF 25/144 reads (17%) | called by mutect2, pindel, varscan2
- NEFM | c.141del p.V48Cfs*61 | Frame Shift Del (DEL) | VAF 14/63 reads (22%) | called by mutect2, pindel, varscan2
- NSD1 | c.2948dup p.D984* | Frame Shift Ins (INS) | VAF 21/113 reads (19%) | called by mutect2, pindel, varscan2
- NSG2 | c.306dup p.E103Rfs*6 | Frame Shift Ins (INS) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- OR4L1 | c.891del p.I298* | Frame Shift Del (DEL) | VAF 39/155 reads (25%) | called by mutect2, pindel, varscan2
- OR56B1 | c.559del p.L187Cfs*34 | Frame Shift Del (DEL) | VAF 27/112 reads (24%) | called by mutect2, pindel, varscan2
- OR6T1 | c.571del p.D191Tfs*5 | Frame Shift Del (DEL) | VAF 14/75 reads (19%) | called by mutect2, pindel, varscan2
- POLR2B | c.3099dup p.G1034Wfs*24 | Frame Shift Ins (INS) | VAF 35/188 reads (19%) | called by mutect2, pindel, varscan2
- RIPK4 | c.289dup p.E97Gfs*65 | Frame Shift Ins (INS) | VAF 16/83 reads (19%) | called by mutect2, pindel, varscan2
- SBF2 | c.5423dup p.H1809Afs*4 | Frame Shift Ins (INS) | VAF 33/182 reads (18%) | called by mutect2, pindel, varscan2
- SLC25A20 | c.288del p.K97Rfs*32 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel
- SPIN3 | c.204del p.W68* | Frame Shift Del (DEL) | VAF 54/172 reads (31%) | called by mutect2, pindel, varscan2
- VARS2 | c.283+8_283+16del p.X95_splice | Splice Site (DEL) | VAF 33/183 reads (18%) | called by mutect2, pindel, varscan2
- XKR4 | c.1371del p.F458Sfs*6 | Frame Shift Del (DEL) | VAF 29/147 reads (20%) | called by mutect2, pindel, varscan2
- XRCC5 | c.847dup p.T283Nfs*17 | Frame Shift Ins (INS) | VAF 27/112 reads (24%) | called by mutect2, pindel, varscan2
- ABCB5 | c.2397C>A p.A799= (on ENST00000404938 / NM_001163941.2; = p.A354= on NM_178559.6) | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV99327535; called by muse, mutect2, varscan2
- ACE2 | c.27C>T p.L9= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs1463669655, COSV53023720, COSV99382573; called by muse, mutect2, varscan2
- ACLY | c.1110G>A p.E370= | Silent (SNP) | VAF 45/200 reads (23%) | catalogued as COSV100709538; called by muse, mutect2, varscan2
- ADAM29 | c.1299T>C p.D433= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as COSV100821917; called by muse, mutect2, varscan2
- ADAMTS16 | c.1932T>C p.S644= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as COSV99940205; called by muse, mutect2, varscan2
- ADGRA1 | c.1257C>G p.G419= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100811003; called by muse, mutect2, varscan2
- ADGRB1 | c.2229G>T p.R743= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100029294; called by muse, mutect2, varscan2
- AFF3 | c.1800C>A p.A600= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV100417942; called by muse, mutect2
- AKAP13 | c.5619T>C p.R1873= (on ENST00000394518 / NM_007200.5; = p.R1877= on NM_006738.6) | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as COSV100773196; called by muse, mutect2, varscan2
- ALDH4A1 | c.624G>T p.S208= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as rs142063145, COSV99311572; called by muse, mutect2, varscan2
- ALDH9A1 | c.81T>C p.T27= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV100699276; called by muse, mutect2, varscan2
- ALPL | c.423C>A p.T141= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV100876796; called by muse, mutect2, varscan2
- ARGLU1 | c.768G>T p.L256= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV101033489; called by muse, mutect2, varscan2
- ATP10D | c.1281G>A p.E427= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV99905250; called by muse, mutect2, varscan2
- BAG2 | c.423A>G p.A141= | Silent (SNP) | VAF 36/193 reads (19%) | catalogued as rs1219678456, COSV100443733; called by muse, mutect2, varscan2
- C8B | c.1023G>C p.G341= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV100980704; called by muse, mutect2, varscan2
- CACNA1E | c.3255G>T p.V1085= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV100701345; called by muse, mutect2, varscan2
- CACNA2D1 | c.3087A>G p.R1029= (on ENST00000356253 / NM_001366867.1; = p.R1017= on NM_000722.4) | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV100666084; called by muse, mutect2, varscan2
- CASP1 | c.843C>A p.I281= (on ENST00000436863 / NM_033292.4; = p.I260= on NM_001223.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV100782728, COSV62057498; called by muse, mutect2, varscan2
- CATSPERE | c.1926C>T p.A642= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV100834944; called by muse, mutect2, varscan2
- CCDC130 | c.741G>A p.R247= | Silent (SNP) | VAF 48/73 reads (66%) | catalogued as rs1025309781, COSV99237249; called by muse, mutect2, varscan2
- CCDC39 | c.822G>T p.G274= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as COSV56484341, COSV99867430; called by muse, mutect2, varscan2
- CCNA1 | c.312C>A p.I104= | Silent (SNP) | VAF 30/137 reads (22%) | catalogued as COSV99714362; called by muse, mutect2, varscan2
- CDC14B | c.963G>T p.T321= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV55786381; called by muse, mutect2, varscan2
- CDH22 | c.1065C>G p.T355= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV100952739, COSV64838382; called by muse, mutect2, varscan2
- CFAP54 | c.6768A>G p.T2256= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as COSV100732986; called by muse, mutect2, varscan2
- CHD6 | c.3732G>C p.L1244= | Silent (SNP) | VAF 28/169 reads (17%) | catalogued as COSV100497819; called by muse, mutect2, varscan2
- CNOT6 | c.174G>A p.L58= | Silent (SNP) | VAF 51/237 reads (22%) | catalogued as COSV99993424; called by muse, mutect2, varscan2
- COL14A1 | c.4953T>G p.T1651= | Silent (SNP) | VAF 29/154 reads (19%) | catalogued as COSV52864551; called by muse, mutect2, varscan2
- COL3A1 | c.2976T>A p.R992= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as COSV100482583; called by muse, mutect2, varscan2
- COL6A6 | c.5598C>A p.I1866= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100649880, COSV62024225; called by muse, mutect2
- COX10 | c.960C>A p.S320= | Silent (SNP) | VAF 25/131 reads (19%) | catalogued as COSV99886044; called by muse, mutect2, varscan2
- CPNE7 | c.1872C>A p.A624= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as COSV99254593; called by muse, mutect2, varscan2
- CR2 | c.2973T>A p.I991= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as COSV100889536; called by muse, mutect2, varscan2
- CRB2 | c.1405C>T p.L469= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs1475912893, COSV100749539; called by muse, mutect2, varscan2
- CSMD3 | c.7581C>A p.S2527= (on ENST00000297405 / NM_001363185.1; = p.S2423= on NM_052900.3) | Silent (SNP) | VAF 31/152 reads (20%) | catalogued as rs556577832, COSV52111096, COSV99826246; called by muse, mutect2, varscan2
- CTTNBP2 | c.321C>G p.P107= | Silent (SNP) | VAF 58/263 reads (22%) | catalogued as COSV99353185; called by muse, mutect2, varscan2
- CUBN | c.8478C>A p.P2826= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV100912119; called by muse, mutect2, varscan2
- DEFA5 | c.189C>T p.A63= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100400410; called by muse, mutect2, varscan2
- DLL3 | c.762C>T p.T254= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV99218778; called by muse, mutect2, varscan2
- DRP2 | c.297C>A p.A99= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as COSV100871810; called by muse, mutect2, varscan2
- ENAH | c.1149A>G p.S383= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as COSV99490161; called by muse, mutect2, varscan2
- EP400 | c.6315G>C p.P2105= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV100200541; called by muse, mutect2, varscan2
- EPB41L4B | c.1656C>A p.A552= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV101000855; called by muse, mutect2, varscan2
- EPB41L4B | c.1584C>T p.N528= | Silent (SNP) | VAF 62/253 reads (25%) | catalogued as COSV101000856; called by muse, mutect2, varscan2
- EPHA5 | c.2784A>T p.I928= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV99896631; called by muse, mutect2, varscan2
- EPHB2 | c.2343C>T p.T781= (on ENST00000400191 / NM_001309193.2; = p.T782= on NM_004442.7) | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as COSV101006789, COSV101006967; called by muse, mutect2
- FAT3 | c.3996G>A p.V1332= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99962545; called by muse, mutect2, varscan2
- FAT4 | c.6123G>A p.L2041= | Silent (SNP) | VAF 53/258 reads (21%) | catalogued as COSV100627357; called by muse, mutect2, varscan2
- FIGN | c.1812G>A p.R604= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as COSV100291643, COSV60766002; called by muse, mutect2, varscan2
- FMN2 | c.1395G>T p.P465= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100143150; called by muse, mutect2
- FPR1 | c.936G>T p.L312= | Silent (SNP) | VAF 28/135 reads (21%) | catalogued as COSV100493944; called by muse, mutect2, varscan2
- GABRA4 | c.1359T>G p.S453= | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as COSV99973584; called by muse, mutect2, varscan2
- GNAI1 | c.327G>T p.V109= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as COSV100650401; called by muse, mutect2, varscan2
- HDAC9 | c.1533G>T p.G511= | Silent (SNP) | VAF 36/166 reads (22%) | catalogued as COSV101286423; called by muse, mutect2, varscan2
- HDLBP | c.3786C>T p.L1262= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs751053890, COSV51468637; called by mutect2, varscan2
- HERC6 | c.1887G>T p.S629= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV52035613, COSV99986358; called by muse, mutect2, varscan2
- HFM1 | c.4029C>T p.P1343= | Silent (SNP) | VAF 26/154 reads (17%) | catalogued as COSV54022757; called by muse, mutect2, varscan2
- HGD | c.606G>A p.E202= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV99380701; called by muse, mutect2, varscan2
- HIVEP3 | c.5232A>G p.V1744= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs1247385739, COSV56023025, COSV99911622; called by muse, mutect2, varscan2
- IFNA21 | c.513C>T p.I171= | Silent (SNP) | VAF 125/345 reads (36%) | catalogued as rs1355743494, COSV101207412; called by muse, mutect2, varscan2
- ILVBL | c.1176G>A p.E392= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as COSV99654600; called by muse, mutect2, varscan2
- KCNMB1 | c.414A>T p.A138= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV99210409; called by muse, mutect2, varscan2
- KCNN1 | c.1182C>G p.A394= | Silent (SNP) | VAF 33/193 reads (17%) | catalogued as rs377567043, COSV99715671; called by muse, mutect2, varscan2
- KIF21B | c.1302G>A p.L434= | Silent (SNP) | VAF 21/144 reads (15%) | catalogued as COSV100143812; called by muse, mutect2, varscan2
- KIR3DL2 | c.1182G>A p.Q394= | Silent (SNP) | VAF 77/362 reads (21%) | catalogued as COSV54391023; called by muse, mutect2, varscan2
- KIRREL3 | c.1209C>A p.P403= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV101375170, COSV69384303; called by muse, mutect2, varscan2
- KLHL31 | c.675A>G p.L225= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as COSV100911737; called by muse, mutect2, varscan2
- KLHL8 | c.207C>T p.V69= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV99911247; called by muse, mutect2, varscan2
- KPNA2 | c.1008A>G p.A336= | Silent (SNP) | VAF 42/232 reads (18%) | catalogued as rs781940531, COSV100388682; called by muse, mutect2, varscan2
- LGR6 | c.1692C>T p.I564= (on ENST00000367278 / NM_001017403.1; = p.I512= on NM_021636.3) | Silent (SNP) | VAF 39/126 reads (31%) | catalogued as rs1343244770, COSV99706174; called by muse, varscan2
- LGR6 | c.2256C>T p.I752= (on ENST00000367278 / NM_001017403.1; = p.I700= on NM_021636.3) | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV99706184; called by muse, mutect2, varscan2
- LGR6 | c.2466C>G p.L822= (on ENST00000367278 / NM_001017403.1; = p.L770= on NM_021636.3) | Silent (SNP) | VAF 74/232 reads (32%) | catalogued as COSV99706193; called by muse, varscan2
- LHFPL2 | c.141G>C p.A47= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100982454; called by muse, mutect2, varscan2
- LPA | c.3957C>G p.T1319= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as COSV100306219; called by muse, mutect2, varscan2
- LRP4 | c.4842C>T p.T1614= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV101066275; called by muse, mutect2, varscan2
- MAGEA3 | c.249C>A p.S83= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as COSV100939000; called by muse, mutect2, varscan2
- MAGEC1 | c.1149C>A p.S383= | Silent (SNP) | VAF 54/164 reads (33%) | catalogued as COSV99594965; called by muse, mutect2, varscan2
- MARK4 | c.696C>T p.Y232= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as rs151153987; called by muse, mutect2, varscan2
- MDGA1 | c.405G>T p.T135= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99776392; called by muse, mutect2
- MED29 | c.618C>T p.V206= (on ENST00000615911; = p.V185= on NM_017592.4) | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs1419034112, COSV100219071; called by muse, mutect2, varscan2
- MROH2B | c.4581C>T p.L1527= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV101270527; called by muse, mutect2, varscan2
- MROH7 | c.387G>A p.L129= | Silent (SNP) | VAF 48/209 reads (23%) | catalogued as COSV100272982; called by muse, mutect2, varscan2
- MSH4 | c.2448T>C p.H816= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as COSV99590790; called by muse, mutect2, varscan2
- MYL10 | c.345G>T p.A115= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs375406824, COSV56207128; called by muse, mutect2, varscan2
- MYO18B | c.5448C>T p.L1816= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs754238505, COSV100122752; called by muse, varscan2
- MYOM2 | c.1566C>A p.I522= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV100036781; called by muse, mutect2, varscan2
- NALCN | c.117C>T p.H39= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs1244971953, COSV99213246; called by muse, mutect2
- NAV3 | c.5440T>C p.L1814= (on ENST00000397909 / NM_001024383.2; = p.L1792= on NM_014903.6) | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as COSV99887395; called by muse, mutect2, varscan2
- NDST4 | c.1368T>A p.P456= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV99995620; called by muse, mutect2, varscan2
- NEFH | c.1548C>A p.A516= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV100151280; called by muse, mutect2, varscan2
- NEUROG2 | c.624C>T p.P208= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100511753; called by muse, mutect2
- NFASC | c.2919C>A p.T973= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs1482704907, COSV100362945; called by muse, mutect2, varscan2
- NYAP2 | c.1431C>T p.P477= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV99795889; called by muse, mutect2, varscan2
- OCRL | c.2652C>T p.R884= | Silent (SNP) | VAF 75/179 reads (42%) | catalogued as COSV63980996; called by muse, mutect2, varscan2
- OR52A1 | c.813C>A p.I271= | Silent (SNP) | VAF 26/128 reads (20%) | catalogued as COSV100200427, COSV100200556, COSV61092161; called by muse, mutect2, varscan2
- OR56B4 | c.870A>G p.A290= | Silent (SNP) | VAF 36/145 reads (25%) | catalogued as COSV100337629; called by muse, mutect2, varscan2
- OR6F1 | c.189G>C p.L63= | Silent (SNP) | VAF 25/189 reads (13%) | catalogued as COSV100128987; called by muse, mutect2, varscan2
- PAG1 | c.795G>T p.L265= | Silent (SNP) | VAF 52/191 reads (27%) | catalogued as COSV99597071; called by muse, mutect2, varscan2
- PARP8 | c.1203G>A p.L401= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as COSV99890162; called by muse, mutect2, varscan2
- PCDH11X | c.915C>A p.T305= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV100008818; called by muse, mutect2, varscan2
- PCK1 | c.1128G>C p.P376= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV100100057, COSV60129172; called by muse, mutect2, varscan2
- PDE3A | c.3312G>C p.L1104= | Silent (SNP) | VAF 28/160 reads (18%) | catalogued as COSV100761759, COSV62978849; called by muse, mutect2, varscan2
- PHC1 | c.1080G>T p.A360= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV101418522, COSV101418682; called by muse, mutect2, varscan2
- PKHD1 | c.3582C>T p.Y1194= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV100581368, COSV61866529; called by muse, mutect2, varscan2
- PPFIA2 | c.2214G>A p.R738= | Silent (SNP) | VAF 42/218 reads (19%) | catalogued as rs752660936, COSV100331840; called by muse, mutect2, varscan2
- PPFIA2 | c.150G>C p.R50= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1417917357, COSV100331841, COSV61043097; called by muse, mutect2, varscan2
- PPL | c.1956G>C p.G652= | Silent (SNP) | VAF 54/199 reads (27%) | catalogued as COSV100630527; called by muse, mutect2
- PRAMEF19 | c.1434T>C p.P478= | Silent (SNP) | VAF 39/180 reads (22%) | called by muse, mutect2, varscan2
- PRAMEF4 | c.192C>T p.R64= | Silent (SNP) | VAF 42/170 reads (25%) | catalogued as COSV99339522; called by muse, mutect2, varscan2
- PRKDC | c.7086G>A p.V2362= | Silent (SNP) | VAF 36/197 reads (18%) | catalogued as COSV100038697; called by muse, mutect2, varscan2
- PSMG1 | c.819A>T p.L273= | Silent (SNP) | VAF 24/135 reads (18%) | catalogued as COSV100521863; called by muse, mutect2, varscan2
- PTPRA | c.27G>T p.L9= | Silent (SNP) | VAF 48/233 reads (21%) | catalogued as COSV99399247; called by muse, mutect2, varscan2
- PTPRJ | c.1146G>A p.L382= | Silent (SNP) | VAF 31/122 reads (25%) | catalogued as rs145270865; called by muse, mutect2, varscan2
- PWWP3A | c.570G>T p.P190= (on ENST00000627377; = p.P189= on NM_032853.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100261800; called by muse, mutect2, varscan2
- RXRB | c.1116G>A p.L372= | Silent (SNP) | VAF 35/63 reads (56%) | catalogued as COSV100553505; called by muse, mutect2, varscan2
- RYR2 | c.5421G>C p.R1807= | Silent (SNP) | VAF 100/345 reads (29%) | catalogued as COSV100768306; called by muse, mutect2, varscan2
- SALL4 | c.111G>A p.A37= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99409222; called by muse, mutect2
- SDK1 | c.324G>T p.T108= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV101268829; called by muse, mutect2, varscan2
- SHISA3 | c.516C>G p.G172= | Silent (SNP) | VAF 50/219 reads (23%) | catalogued as COSV100069788; called by muse, mutect2, varscan2
- SIM1 | c.1350G>T p.A450= | Silent (SNP) | VAF 44/114 reads (39%) | catalogued as rs752488752, COSV53492624, COSV99492011; called by muse, mutect2, varscan2
- SIM2 | c.1161C>T p.P387= | Silent (SNP) | VAF 40/143 reads (28%) | catalogued as rs756174339, COSV99292842, COSV99292915; called by muse, mutect2, varscan2
- SLC10A4 | c.957T>A p.A319= | Silent (SNP) | VAF 50/230 reads (22%) | catalogued as COSV99906781; called by muse, mutect2, varscan2
- SLC26A11 | c.291C>G p.S97= | Silent (SNP) | VAF 45/227 reads (20%) | catalogued as COSV100413327; called by muse, mutect2, varscan2
- SLC52A1 | c.771G>T p.P257= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV99643328; called by muse, mutect2, varscan2
- SLC8A1 | c.249G>C p.V83= | Silent (SNP) | VAF 46/186 reads (25%) | catalogued as rs1291770639, COSV100244762; called by muse, mutect2, varscan2
- SNAPC4 | c.2379G>A p.L793= | Silent (SNP) | VAF 111/321 reads (35%) | catalogued as rs770245394, COSV100046854; called by muse, mutect2, varscan2
- SPHKAP | c.3771C>A p.A1257= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV100763752; called by muse, mutect2, varscan2
- SPRR1B | c.177C>A p.P59= | Silent (SNP) | VAF 36/248 reads (15%) | catalogued as COSV100198327, COSV61067881; called by muse, mutect2
- SPTA1 | c.636G>T p.G212= | Silent (SNP) | VAF 49/186 reads (26%) | catalogued as COSV100934401, COSV63749830; called by muse, mutect2, varscan2
- STEAP4 | c.930G>T p.V310= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV100112414; called by muse, mutect2, varscan2
- STRADB | c.972A>G p.T324= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as COSV99524310; called by muse, mutect2, varscan2
- TAF1L | c.1347T>A p.G449= | Silent (SNP) | VAF 80/245 reads (33%) | catalogued as rs55679392, COSV99644184; called by muse, mutect2, varscan2
- TAS2R41 | c.471A>G p.Q157= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV101281472; called by muse, mutect2, varscan2
- TBC1D9B | c.3159C>A p.T1053= (on ENST00000356834 / NM_198868.3; = p.T1036= on NM_015043.4) | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV100783443; called by muse, mutect2, varscan2
- TBR1 | c.1164A>G p.A388= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as COSV101271415; called by muse, mutect2, varscan2
- THSD7A | c.774G>T p.G258= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as COSV101448560; called by muse, mutect2, varscan2
- TMEM132E | c.1698C>G p.T566= (on ENST00000321639; = p.T656= on NM_001304438.2) | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100395984; called by muse, mutect2
- TOP1 | c.1251A>T p.T417= | Silent (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2
- TRPA1 | c.852C>A p.A284= | Silent (SNP) | VAF 31/101 reads (31%) | catalogued as COSV100083319; called by muse, mutect2, varscan2
- TSNARE1 | c.429C>T p.H143= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs746186911, COSV100209936; called by muse, mutect2, varscan2
- TTC39B | c.375A>G p.S125= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs138159733; called by muse, mutect2, varscan2
- TTN | c.70746A>T p.T23582= (on ENST00000591111; = p.T16158= on NM_003319.4) | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100596633; called by muse, mutect2, varscan2
- U2SURP | c.822T>C p.T274= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV101204350; called by muse, mutect2, varscan2
- UBN1 | c.2952G>T p.V984= | Silent (SNP) | VAF 59/154 reads (38%) | catalogued as COSV99277523; called by muse, mutect2, varscan2
- UBXN6 | c.594G>A p.K198= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as COSV100010869; called by muse, mutect2, varscan2
- UFM1 | c.36G>T p.S12= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as COSV99522597; called by muse, mutect2, varscan2
- UGT2B4 | c.450A>G p.A150= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100522222; called by muse, mutect2, varscan2
- USH2A | c.13011G>C p.T4337= | Silent (SNP) | VAF 34/143 reads (24%) | catalogued as rs768134583, COSV100229851; called by muse, mutect2, varscan2
- USH2A | c.11571G>A p.R3857= | Silent (SNP) | VAF 25/175 reads (14%) | catalogued as rs1220012995, COSV100229854; called by muse, mutect2, varscan2
- WLS | c.1631G>A p.*544= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as COSV100699580; called by muse, mutect2, varscan2
- ZBTB16 | c.1833C>A p.S611= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as COSV100251041; called by muse, mutect2, varscan2
- ZBTB20 | c.1866C>A p.I622= (on ENST00000474710 / NM_001164342.2; = p.I549= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as rs148654668; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83758G>T | Intron (SNP) | VAF 42/221 reads (19%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845751 T>A | 5'Flank (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- EYA4 | c.1757-96T>C | Intron (SNP) | VAF 22/113 reads (19%) | catalogued as COSV100765231; called by muse, mutect2, varscan2
- FRMPD2B | n.946G>T | RNA (SNP) | VAF 44/398 reads (11%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1461G>T | RNA (SNP) | VAF 12/80 reads (15%) | catalogued as rs551210403; called by muse, mutect2, varscan2
- LINC01587 | n.327G>C | RNA (SNP) | VAF 15/61 reads (25%) | catalogued as rs1435450082; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.821C>T | RNA (SNP) | VAF 11/66 reads (17%) | called by muse, mutect2, varscan2
- NRG1 | c.502+31440C>A | Intron (SNP) | VAF 19/71 reads (27%) | catalogued as rs76552623, COSV99827786; called by muse, mutect2, varscan2
- NRXN1 | c.3365-109738C>T | Intron (SNP) | VAF 19/55 reads (35%) | catalogued as COSV100453558, COSV100456450; called by muse, mutect2, varscan2
- PSG1 | c.1243+33T>A | Intron (SNP) | VAF 95/425 reads (22%) | catalogued as rs1299366716, COSV99738848; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791785 T>A | 3'Flank (SNP) | VAF 17/66 reads (26%) | called by muse, varscan2
- RN7SL484P | chr15:99791831 A>T | 3'Flank (SNP) | VAF 19/65 reads (29%) | called by muse, varscan2
